CCDI case PBCJXL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/3dcef6c9-4540-45c0-b278-afd3f5470180

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ganglioneuroma: ICD-O-3 morphology code: 9490/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.8 years (4,664 days).

Biospecimens (3 samples)
- Sample 0DTHLY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTHM9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTHMF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
